CCDI case PBBVWM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/44714387-b863-4ba2-9c96-098a9909ccdc

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Large cell medulloblastoma: ICD-O-3 morphology code: 9474/3; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 1.3 years (473 days).

Biospecimens (2 samples)
- Sample 0DIPKP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIPKZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
